Somatic mutation profile of tumor specimen TCGA-XE-AAOL-01A (aliquot TCGA-XE-AAOL-01A-11D-A435-10) from TCGA case TCGA-XE-AAOL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 39.0 years (14,230 days).
Specimen TCGA-XE-AAOL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1573ff25-7f3c-46e1-bee8-8127aadea558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AAOL-10A (Blood Derived Normal), aliquot TCGA-XE-AAOL-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eec8a514-1f69-40a5-9631-1045d64291b4

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1, RNA 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSW | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV100327553; called by muse, mutect2
- GUK1 | c.391-2A>G p.X131_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as rs955712851; called by muse, mutect2, varscan2
- BOD1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CSMD2 | c.1897G>T p.V633F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- IL1RL1 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- LRRC37A | c.2815T>G p.L939V | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LSS | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- NPR2 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF182 | c.563T>G p.L188W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RTL1 | c.334del p.D112Ifs*10 | Frame Shift Del (DEL) | VAF 62/154 reads (40%) | called by mutect2, varscan2
- TRIM45 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF268 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.061); called by muse, mutect2
- KRT6B | c.1362C>T p.V454= | Silent (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- TCTEX1D4 | c.630C>T p.F210= | Silent (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- TRPC7 | c.552G>A p.L184= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs747505700; called by muse, mutect2, varscan2
- ANKRD54 | chr22:37844337 C>A | 5'Flank (SNP) | VAF 4/12 reads (33%) | catalogued as rs753844117; called by muse, varscan2
- C5orf34 | c.1679+47A>T | Intron (SNP) | VAF 52/121 reads (43%) | catalogued as rs556300276, COSV100175691; called by muse, mutect2, varscan2
- CLN5 | c.*270dup | 3'UTR (INS) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- LRRC37A17P | n.3979T>A | RNA (SNP) | VAF 2/31 reads (6%) | called by muse, mutect2
- SPTBN1 | c.6420+89G>T | Intron (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
